Somatic mutation profile of tumor specimen TCGA-FB-AAQ1-01A (aliquot TCGA-FB-AAQ1-01A-12D-A40W-08) from TCGA case TCGA-FB-AAQ1, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 49.8 years (18,172 days).
Specimen TCGA-FB-AAQ1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80f87658-4a92-4fbd-a76a-f554d3dba663.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FB-AAQ1-11A (Solid Tissue Normal), aliquot TCGA-FB-AAQ1-11A-11D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f107b4e7-2e71-4a0d-a709-1336f2d96738

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 22, Silent 13, Frame Shift Ins 2, In Frame Ins 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 45/231 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.216dup p.V73Rfs*76 | Frame Shift Ins (INS) | VAF 172/730 reads (24%) | catalogued as rs730882018, COSV104369723; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ATP8B2 | c.1864G>A p.A622T (on ENST00000672630; = p.A589T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs141457358; called by muse, mutect2, varscan2
- BAP1 | c.343A>C p.M115L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99964423; called by muse, varscan2
- BCHE | c.1028C>A p.T343N | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.86); catalogued as COSV52259087; called by muse, mutect2
- BEND4 | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as rs374001079; called by muse, mutect2, varscan2
- CD81 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 76/386 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV99719261; called by muse, mutect2, varscan2
- DNAH10 | c.10141G>A p.A3381T (on ENST00000409039; = p.A3320T on NM_207437.3) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373522460; called by muse, mutect2, varscan2
- GRIN2B | c.2639G>A p.R880H | Missense Mutation (SNP) | VAF 113/686 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.871); catalogued as rs904771425, COSV74205198, COSV74206925; called by muse, mutect2, varscan2
- HECW2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 72/652 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1284621782, COSV53673584; called by muse, mutect2, varscan2
- IL31RA | c.1353C>T p.G451= | Splice Region (SNP) | VAF 42/292 reads (14%) | catalogued as rs755336880, COSV51683619; called by muse, mutect2, varscan2
- IP6K3 | c.827C>A p.S276* | Nonsense Mutation (SNP) | VAF 29/282 reads (10%) | catalogued as COSV99540105; called by muse, mutect2
- NIPBL | c.1753A>G p.I585V | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as CD128913, COSV99242357; called by muse, mutect2
- ODF2 | c.1843G>T p.D615Y (on ENST00000434106 / NM_153433.2; = p.D591Y on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63546075; called by muse, mutect2, varscan2
- OXCT2 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 45/425 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.805); catalogued as COSV100560371; called by muse, mutect2, varscan2
- PRAM1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.026); catalogued as COSV99725832; called by muse, mutect2
- RELN | c.6854G>A p.R2285H | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs116394157, COSV100634722; called by muse, mutect2, varscan2
- SAMM50 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 151/587 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); catalogued as COSV100601461; called by muse, mutect2, varscan2
- SGSM1 | c.2561C>T p.T854M (on ENST00000400359 / NM_001039948.4; = p.T793M on NM_133454.3) | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as rs376575281; called by muse, mutect2, varscan2
- SLC7A7 | c.1094A>T p.N365I | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV99591296; called by muse, mutect2, varscan2
- SPINK5 | c.3005T>C p.I1002T | Missense Mutation (SNP) | VAF 157/899 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.3); catalogued as COSV99807253; called by muse, mutect2, varscan2
- STOX2 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs766946457, COSV100409176; called by muse, varscan2
- TAFA2 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 53/240 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as COSV101353854, COSV69172342; called by muse, mutect2, varscan2
- VWA7 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 53/475 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as rs576229707, COSV100991959; called by muse, mutect2, varscan2
- BSN | c.392_394dup p.V131dup | In Frame Ins (INS) | VAF 31/155 reads (20%) | called by mutect2, pindel, varscan2
- MYRF | c.2947dup p.R983Pfs*15 (on ENST00000278836 / NM_001127392.3; = p.R948Pfs*15 on NM_013279.4) | Frame Shift Ins (INS) | VAF 55/311 reads (18%) | called by mutect2, pindel, varscan2
- OR8G2P | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CILP2 | c.2232C>T p.Y744= | Silent (SNP) | VAF 21/174 reads (12%) | catalogued as rs1406277815, COSV99365134; called by muse, mutect2, varscan2
- DCLK3 | c.1620C>T p.G540= | Silent (SNP) | VAF 148/817 reads (18%) | catalogued as rs771625779, COSV69363723; called by muse, mutect2, varscan2
- EBF2 | c.492C>T p.C164= | Silent (SNP) | VAF 83/436 reads (19%) | catalogued as rs1295944090, COSV101282278; called by muse, mutect2, varscan2
- FBXO33 | c.1473C>T p.T491= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs200556309, COSV99981028, COSV99981042; called by muse, mutect2, varscan2
- FZD7 | c.633C>T p.P211= | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs1313182169, COSV99637444; called by muse, mutect2
- HAS1 | c.1338G>A p.A446= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs746209555, COSV99708577; called by muse, mutect2, varscan2
- KCNB2 | c.666C>T p.D222= | Silent (SNP) | VAF 95/450 reads (21%) | catalogued as rs768533276, COSV101578973; called by muse, mutect2, varscan2
- PRDM10 | c.1503C>T p.D501= | Silent (SNP) | VAF 64/345 reads (19%) | catalogued as rs866087947, COSV100456555; called by muse, mutect2, varscan2
- SLC22A16 | c.774T>C p.A258= | Silent (SNP) | VAF 65/274 reads (24%) | catalogued as COSV100397903; called by muse, mutect2, varscan2
- THADA | c.2428C>T p.L810= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV100369395; called by muse, mutect2, varscan2
- TIGD2 | c.120C>A p.S40= | Silent (SNP) | VAF 45/342 reads (13%) | catalogued as COSV100392463; called by muse, mutect2, varscan2
- VARS1 | c.2757C>T p.T919= | Silent (SNP) | VAF 70/368 reads (19%) | catalogued as rs745663284, COSV100791852; called by muse, mutect2, varscan2
- ZSCAN18 | c.411G>T p.L137= | Silent (SNP) | VAF 42/317 reads (13%) | catalogued as rs369976525; called by muse, mutect2, varscan2
